Somatic mutation profile of tumor specimen TCGA-XE-AAO4-01A (aliquot TCGA-XE-AAO4-01A-11D-A435-10) from TCGA case TCGA-XE-AAO4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 40.9 years (14,930 days).
Specimen TCGA-XE-AAO4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4faf987d-06b2-45b7-ac61-3dcd6a2c9b33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAO4-10A (Blood Derived Normal), aliquot TCGA-XE-AAO4-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1ffe1ae-2969-4f83-ba66-c3d7d006cbb9

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 3, Intron 2, 5'Flank 1, Splice Region 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 71/178 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATCAY | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as COSV100008811; called by muse, mutect2, varscan2
- CLDN14 | c.447C>A p.N149K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV59778415; called by muse, mutect2, varscan2
- CYP2A6 | c.565del p.D189Tfs*16 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | catalogued as COSV56537358; called by mutect2, pindel, varscan2
- EFCAB5 | c.2251A>C p.I751L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100300427, COSV57931141; called by muse, mutect2, varscan2
- GTF2I | c.237T>C p.Y79= | Splice Region (SNP) | VAF 27/227 reads (12%) | catalogued as COSV60404416; called by muse, mutect2, varscan2
- LAMA5 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556381906, COSV53376320; called by muse, mutect2
- N6AMT1 | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs752813073; called by muse, mutect2, varscan2
- PTPRO | c.2827G>C p.E943Q (on ENST00000281171 / NM_030667.3; = p.E915Q on NM_002848.4) | Missense Mutation (SNP) | VAF 137/1408 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.984); catalogued as COSV55513924; called by muse, mutect2
- SPAG7 | c.506A>G p.H169R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs574343509; called by muse, mutect2, varscan2
- TOP1MT | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs200437445; called by muse, mutect2, varscan2
- YTHDF3 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.27); catalogued as rs1174148188, COSV72773342; called by muse, mutect2, varscan2
- ADAM21 | c.1694G>A p.C565Y | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM23 | c.1485G>T p.R495S | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- ALDH1B1 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ARSG | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- KDM2A | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- KMT2B | c.6731C>G p.P2244R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIG3 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAGEC1 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NELFA | c.49G>A p.E17K (on ENST00000542778; = p.E6K on NM_005663.5) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NFX1 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- NPC1L1 | c.3791T>A p.I1264N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5C1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- REXO1 | c.1871C>G p.T624S | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- RPS6KA5 | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNW1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF251 | c.653T>C p.F218S | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GAREM2 | c.2214C>T p.G738= | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- NOTCH2 | c.4116G>A p.R1372= | Silent (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- ZNF536 | c.3519C>A p.S1173= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- ANKFY1 | c.458+37G>C | Intron (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- APLN | c.*154C>A | 3'UTR (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- CFAP47 | c.5536-543C>A | Intron (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- CTBP1 | chr4:1250811 G>A | 5'Flank (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.372A>G | RNA (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
